Surgical pathology report (de-identified scan), TCGA case TCGA-32-1979, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-1979-01A (Primary Tumor).

NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

1. Brain tumor
2. Brain tumor

GBM [REDACTED]
CONTROL [REDACTED]

CLINICAL DIAGNOSIS:

Brain tumor

TCGA-32-1979

GROSS DESCRIPTION:

1. Received fresh for frozen section are multiple tan-red soft tissues aggregating to 1.4 x 1.2 x 0.2 cm. A smear is performed. Entirely frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

GLIOBLASTOMA. [REDACTED]

Tissue submitted for frozen is subsequently submitted for permanent.

2. Received in formalin labeled with the patient's name and "brain tumor" are multiple portions of tan to brown soft tissue aggregating to 3.0 x 2.0 x 1.0 cm. The largest portion is bivalved. The specimen is entirely submitted in three cassettes.

MICROSCOPIC DESCRIPTION:

- 1, 2. Sections demonstrate a markedly hypercellular glial neoplasm consisting of a proliferation of tumor cells which resemble astrocytes. The neoplastic cells exhibit predominantly elongated nuclei and prominent fibrillary processes. They demonstrate moderate cytologic atypia. Scattered mitotic figures are seen. Both pseudopalisading necrosis as well as microvascular proliferation are readily identified. These histologic features are consistent with a glioblastoma.

DIAGNOSIS:

(PROVISIONAL):

- 1, 2. BRAIN TUMOR, BIOPSY AND RESECTION:

DIAGNOSIS:

GLIOBLASTOMA (WHO GRADE IV).

ADDENDUM NEUROPATHOLOGY REPORT

ADDENDUM DISCUSSION:

Less than 10% of the tumor cells express MGMT.

ADDENDUM DIAGNOSIS:

- 1, 2. BRAIN TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA (WHO GRADE IV).
- <10% TUMOR CELLS POSITIVE FOR MGMT.

Source: NCI Genomic Data Commons file 23f5d7e5-8c4f-4435-8360-3e2ac703b1c7 (TCGA-32-1979.102DA0B4-1D6A-49C8-95B4-263021CA7E7C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).